HCMI case HCM-CSHL-0164-C20 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6058fb8d-eb5d-4dbc-b939-7e92c7cd2776

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Year of birth: 1966; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C78.7; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Liver; Classification of tumor: metastasis; Age at diagnosis: 51.5 years (18,816 days); Prior malignancy: no; Synchronous malignancy: No; Prior treatment: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Irinotecan + Leucovorin Calcium + Oxaliplatin; Treatment intent type: Neoadjuvant; Regimen or line of therapy: FOLFOXIRI; Days to treatment start: 37 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Leucovorin Calcium + Oxaliplatin; Treatment intent type: Neoadjuvant; Regimen or line of therapy: FOLFOX; Days to treatment start: 37 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Fluorouracil + Leucovorin Calcium + Oxaliplatin; Treatment intent type: Maintenance Therapy; Initial disease status: Progressive Disease; Regimen or line of therapy: FOLFOX; Days to treatment start: 37 days; Days to treatment end: 163 days; Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Fluorouracil + Irinotecan + Leucovorin Calcium + Oxaliplatin; Treatment intent type: Maintenance Therapy; Initial disease status: Progressive Disease; Regimen or line of therapy: FOLFOXIRI; Days to treatment start: 37 days; Days to treatment end: 163 days; Treatment outcome: Treatment Ongoing.
   Recorded as not given: neoadjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 281 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Liver; Days to progression: 281 days.
- Follow-up contact recording only the day: day 287.

Molecular and laboratory tests
- CEA: 8.5.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 68.03 kg; Height: 160 cm; BMI: 27.
- Timepoint category: Prior to Diagnosis; Comorbidities: Colon Polyps; Risk factors: Colon Polyps.

Exposures
- Tobacco smoking status: Current Smoker.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-CSHL-0164-C20-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-0164-C20-06A-01-S1-HE: Section location: Top; Percent tumor cells: 68; Percent tumor nuclei: 92; Percent normal cells: 0; Percent necrosis: 7; Percent stromal cells: 25; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
  Slide HCM-CSHL-0164-C20-06A-01-S2-HE: Section location: Bottom; Percent tumor cells: 47; Percent tumor nuclei: 90; Percent normal cells: 3; Percent necrosis: 20; Percent stromal cells: 30; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
- Sample HCM-CSHL-0164-C20-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-0164-C20-11A-01-S2-HE: Section location: Bottom; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 67; Percent necrosis: 0; Percent stromal cells: 33; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
  Slide HCM-CSHL-0164-C20-11A-01-S1-HE: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 75; Percent necrosis: 0; Percent stromal cells: 25; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
- Sample HCM-CSHL-0164-C20-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
